Somatic mutation profile of tumor specimen TCGA-55-6543-01A (aliquot TCGA-55-6543-01A-11D-1753-08) from TCGA case TCGA-55-6543, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-55-6543-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 213c9ec5-b8c5-4885-a56b-9c2eb790e018.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6543-10A (Blood Derived Normal), aliquot TCGA-55-6543-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b2e43e5-e9c7-478f-ac1c-cc5494b5cc8f

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH2 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as rs762121316, CM102587, COSV55447979; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL9L | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763468079, COSV52688739; called by muse, mutect2, varscan2
- DNER | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766886541, COSV100519074, COSV59164215; called by muse, mutect2
- DROSHA | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV60782526; called by muse, mutect2, varscan2
- F9 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as CM094077, CM940499, COSV54382335; called by muse, mutect2, varscan2
- FGD1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as rs764048528, COSV64309650; called by muse, mutect2, varscan2
- LRRC2 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56128775; called by muse, mutect2, varscan2
- MYOM3 | c.3067C>T p.R1023W | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs928544232, COSV58400734; called by muse, mutect2
- NUP214 | c.3679A>T p.I1227L | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.046); catalogued as rs1242683701, COSV63913085; called by muse, mutect2, varscan2
- OR4K2 | c.162C>A p.H54Q | Missense Mutation (SNP) | VAF 152/325 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV100063901, COSV53851601; called by muse, mutect2, varscan2
- PPP2R2B | c.493C>T p.R165* (on ENST00000394409; = p.R231* on NM_181674.2) | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV60778987; called by muse, mutect2, varscan2
- PSME1 | c.480G>C p.M160I | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0.253); catalogued as COSV52825860; called by muse, mutect2
- SMARCA4 | c.4412A>G p.K1471R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as COSV60808717; called by muse, mutect2, varscan2
- SPIN2B | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV99328192; called by mutect2, varscan2
- STAG3 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs765988932, COSV57927518; called by muse, mutect2, varscan2
- U2AF2 | c.11T>A p.F4Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV58276294; called by muse, mutect2
- PDE9A | c.1326del p.F442Lfs*9 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- TOB2 | c.435_450del p.Q146Pfs*41 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- TRAV2 | c.247T>A p.Y83N | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CUL4B | c.2589A>T p.T863= | Silent (SNP) | VAF 75/453 reads (17%) | catalogued as COSV60691065; called by muse, mutect2, varscan2
- DHDH | c.723C>T p.S241= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs1400759249, COSV55483334; called by muse, mutect2, varscan2
- NUDT19 | c.240C>T p.F80= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV67959600; called by mutect2, varscan2
- SEC31B | c.2187G>C p.R729= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV64845701; called by muse, mutect2, varscan2
- SRRT | c.180G>A p.R60= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV61454582; called by muse, mutect2, varscan2
